Somatic mutation profile of tumor specimen TCGA-P5-A5F6-01A (aliquot TCGA-P5-A5F6-01A-11D-A289-08) from TCGA case TCGA-P5-A5F6, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 26.2 years (9,575 days).
Specimen TCGA-P5-A5F6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 233184b0-ffe4-4a23-a1f9-7deebb3248fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5F6-10A (Blood Derived Normal), aliquot TCGA-P5-A5F6-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aa5c8a6-7ad5-499e-b9d7-5a3123285d02

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRIT1 | c.453A>G p.T151= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV60670207; called by muse, mutect2, varscan2
- KRT2 | c.312T>C p.G104= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs75253159, COSV59008973, COSV59009587, COSV59009958; called by muse, varscan2
